Gene-level copy-number profile of tumor specimen ALCH-AESE-TTP1-A from ALCHEMIST case ALCH-AESE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 44.0 years (16,065 days).
Specimen ALCH-AESE-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a8d1acbf-43f1-4554-860d-d3a34eac6deb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AESE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/84561e72-3e97-48ef-a96e-75b39c235136

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,391; copy number 2: 45,024; copy number 3: 8,567; copy number 4: 196; copy number 5: 61; copy number 6: 4; copy number 7: 26; copy number 8: 81; copy number 10: 14; copy number 11: 33.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:88,382,959–88,440,757, 1 gene: ZNF469.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 219 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:57,723,761–58,105,935, 28 genes, copy number 5: AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr12:59,523,278–60,419,293, 11 genes, copy number 5: LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr12:61,708,259–62,279,150, 1 gene, copy number 5 (within-gene range 4–5): TAFA2.
- chr12:61,879,318–63,055,765, 25 genes, copy number 5–6: KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5.
- chr12:63,844,700–64,162,217, 1 gene, copy number 10 (within-gene range 4–10): SRGAP1.
- chr12:64,032,412–70,543,040, 153 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,391. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
